Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6513, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6513-01A (Primary Tumor).

Examination: Histopathological examination

Material: 1. Total organ resection – colon and rectum

TCGA – EI – 6513

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the rectosigmoid junction.**

Examination performed on:

Macroscopic description:

14.8 cm length of large intestine with fat tissue of 3.5 cm in thickness. Cauliflower-shaped tumour sized 6.1 x 7.4 x 3.4 cm found in the mucosa. The lesion surrounds 80% of the intestine circumference, located 5.8 cm from one of the excision lines and 5.9 cm from the opposite line, wall injected with blue dye.

Apart from the tumour, a polyp 0.9 cm in diameter.

Microscopic description:

Adenocarcinoma tubulopapillare (G2).

Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae mesorecti.

Incision line clear of neoplastic lesions.

Metastases carcinomatosae in lymphonodis (NO II/XIII).

Outside the tumour: Adenoma tubulare cum dysplasia gradus levioris.

Histopathological diagnosis:

Adenocarcinoma tubulopapillare coli. Tubulopapillar adenocarcinoma of the colon.

Metastases carcinomatosae in lymphonodis (No II/XIII). Cancer metastases in the lymph nodes (No II/XIII)

(G2, Dukes C, Astler-Collier C2, pT3, pN1, R0).

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file b0f3fe7e-e755-4a3f-bfbc-537738358eab (TCGA-EI-6513.C5FEC294-CEE9-4E64-BC35-DBC9CA0912EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).